Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A42Z, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A42Z-01A (Primary Tumor).

Procurement Date: laterality: Malignant melanoma

Path Report: SKIN TISSUE CHECKLIST

Specimen type: Surgical resection

Tumor site: Skin Non-glabrous, per TSS.

Tumor size: 3 x 3 x 1 cm

Tumor features: Ulcerated, Pigmented

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade: Poorly differentiated

Lymph nodes: 1/10 positive for metastasis (Right inguinal lymph node 1/10)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Breslow depth 10mm

Comments: None

ICD-O-3
melanoma, NOS
8720/3

Site: SKIN, NOS
C44.9

8-3-12
RD

Source: NCI Genomic Data Commons file 7477cdad-98fa-480c-8ae4-2c0b62d8d533 (TCGA-EB-A42Z.71C108F9-92F6-4DB0-BD3B-6E3DC8427E03.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).